Somatic mutation profile of tumor specimen MP2PRT-PARXIG-TMP1-A (aliquot MP2PRT-PARXIG-TMP1-A-1-0-D-A835-36) from MP2PRT case MP2PRT-PARXIG, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Precursor cell lymphoblastic leukemia, NOS; Tissue or organ of origin: Blood; Age at diagnosis: 6.9 years (2,533 days).
Specimen MP2PRT-PARXIG-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 487ec42c-d3ed-40d1-bce2-4d3fa12b6777.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PARXIG-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PARXIG-NB1-A-1-0-D-A835-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e13212ba-427e-4599-9cfb-55ad1a0c4287

The open-access MAF lists 11 somatic variants for this specimen: 10 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 8, Nonsense Mutation 1, Splice Region 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PKLR | c.1291G>A p.A431T | Missense Mutation (SNP) | VAF 168/647 reads (26%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.642); catalogued as rs762591322, CM981573, COSV100712843; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- MYADML2 | c.905G>A p.R302H | Missense Mutation (SNP) | VAF 98/220 reads (45%) | SIFT tolerated (0.57); PolyPhen benign (0.048); catalogued as rs548416662, COSV57999874; called by muse, varscan2
- POTEE | c.950C>A p.S317* | Nonsense Mutation (SNP) | VAF 53/397 reads (13%) | catalogued as COSV58230954; called by muse, mutect2, varscan2
- SEMA3G | c.552C>T p.D184= | Splice Region (SNP) | VAF 112/406 reads (28%) | catalogued as rs200805845; called by muse, varscan2
- ATP8B4 | c.2075C>A p.T692N | Missense Mutation (SNP) | VAF 88/433 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- BRIX1 | c.458A>C p.K153T | Missense Mutation (SNP) | VAF 77/307 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, varscan2
- CHD6 | c.2266G>A p.E756K | Missense Mutation (SNP) | VAF 12/348 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, mutect2
- DRD4 | c.28G>T p.D10Y | Missense Mutation (SNP) | VAF 269/983 reads (27%) | SIFT tolerated (0.06); PolyPhen benign (0.26); called by muse, varscan2
- MAGEC3 | c.803A>C p.Q268P | Missense Mutation (SNP) | VAF 26/243 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.942); called by muse, mutect2, varscan2
- ZNF585A | c.1342A>T p.T448S (on ENST00000292841 / NM_001288800.2; = p.T393S on NM_152655.3) | Missense Mutation (SNP) | VAF 85/333 reads (26%) | SIFT tolerated (1); PolyPhen probably damaging (0.945); called by muse, mutect2, varscan2
- MAGEC3 | c.804G>A p.Q268= | Silent (SNP) | VAF 27/246 reads (11%) | catalogued as COSV100026401; called by muse, mutect2, varscan2
